Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J3, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J3-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Sex: Female

ICD-O-3
Carcinoma, adrenal cortical
8370/3
Site: ① Adrenal Gland
Cortex 074.0
940 1/30/13

Macroscopy

One vessel containing a material immersed in formaldehyde solution, described as following: product of segmental resection of the left kidney and an adrenal mass, previously sectioned, measuring 13 x 8 x 4 cm. The adrenal mass measures 6 x 5 x 4 cm, weights 38 g and the internal surface is characterized by an homogeneous light-brown tissue surrounded by a rim of dark yellow tissue. Macroscopically, no areas of necrosis are evident. Macroscopic invasion of the renal vein is evident.

Conclusion:

Product of left nephrectomy and adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 6 cm.
- Weight – 38 g
- Nuclear grade (Fuhrman) – 3
- Diffuse architectural pattern – present
- Clear cells in < 25% of the neoplasm – present
- Areas on necrosis – present (focally)
- Mitotic count – less than 5 in 50 H.P.F.
- Atypical mitosis – not detected
- Capsular invasion – not detected
- Venous invasion – present
- Sinusoidal invasion – not detected

[page 2 of 2]
- WEISS SCORE = 5
- Presence of a neoplastic thrombus within the renal vein.
- Absence of metastasis in four dissected lymph nodes.

Criteria	1/4/13	Yes	No
Histopathology Discrepancy			✓
Metastatic Discrepancy History			✓

Source: NCI Genomic Data Commons file bcc884eb-a009-4504-b42a-c7fa6e61ecab (TCGA-OR-A5J3.83F53610-4F40-425B-9B69-BBB94234224F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).